Somatic mutation profile of tumor specimen TARGET-30-PAITEG-01A (aliquot TARGET-30-PAITEG-01A-01W) from TARGET case TARGET-30-PAITEG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 2.8 years (1,034 days).
Specimen TARGET-30-PAITEG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad187c21-588f-46d3-9056-8bc8b3e88680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAITEG-10A (Blood Derived Normal), aliquot TARGET-30-PAITEG-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65dea37e-2ca3-4b75-8141-330f3b9655f7

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 19, Silent 9, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHST3 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs771866012, COSV64151599; ClinVar: pathogenic; called by muse, varscan2
- ATG2B | c.5783G>A p.G1928D | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55891811; called by muse, mutect2, varscan2
- BTNL2 | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 32/1012 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.777); catalogued as rs929437861; called by muse, mutect2
- CDK17 | c.361C>G p.Q121E | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.194); catalogued as COSV54135036; called by muse, mutect2
- GPC4 | c.1139C>T p.T380I | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV63698815; called by muse, mutect2
- HNRNPL | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.916); catalogued as COSV55494993; called by muse, mutect2, varscan2
- KCNH3 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as rs771528862, COSV57792361; called by mutect2, varscan2
- MATN1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.903); catalogued as COSV65651274; called by muse, mutect2, varscan2
- MYLPF | c.478A>C p.I160L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.817); catalogued as COSV58443301; called by muse, mutect2, varscan2
- SAMD7 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV59417969; called by muse, mutect2
- SND1 | c.2449G>A p.V817I | Missense Mutation (SNP) | VAF 63/402 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs144250740, COSV61247302; called by muse, varscan2
- TMC7 | c.1460G>A p.W487* | Nonsense Mutation (SNP) | VAF 139/355 reads (39%) | catalogued as COSV58586937; called by muse, varscan2
- TRIM75P | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as COSV72295829; called by muse, mutect2, varscan2
- VDR | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV99968732; called by muse, mutect2
- KIF3B | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OIT3 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- PCYOX1 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRN2 | c.1756G>A p.G586R | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- SPATA4 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.19); called by muse, mutect2
- TRIM13 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABL1 | c.630C>T p.I210= | Silent (SNP) | VAF 25/280 reads (9%) | catalogued as rs756057097; called by muse, mutect2
- CUL9 | c.3096C>T p.P1032= | Silent (SNP) | VAF 105/716 reads (15%) | catalogued as COSV52733003; called by muse, mutect2, varscan2
- DRD1 | c.1077G>A p.E359= | Silent (SNP) | VAF 22/540 reads (4%) | called by muse, mutect2
- FEM1A | c.1131C>T p.I377= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV54164688; called by muse, mutect2, varscan2
- FLAD1 | c.1731G>A p.E577= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV52698914; called by muse, mutect2
- KALRN | c.5313G>A p.L1771= (on ENST00000360013 / NM_001024660.4; = p.L74= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV52262682; called by muse, varscan2
- KLB | c.1678C>T p.L560= | Silent (SNP) | VAF 53/182 reads (29%) | catalogued as COSV57304440; called by muse, mutect2, varscan2
- RO60 | c.390G>A p.Q130= | Silent (SNP) | VAF 36/235 reads (15%) | catalogued as rs1293758229, COSV66474680; called by muse, mutect2, varscan2
- TACC2 | c.2823G>A p.L941= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs1183848172; called by muse, mutect2
